Somatic mutation profile of tumor specimen TCGA-S7-A7WX-01A (aliquot TCGA-S7-A7WX-01A-11D-A35I-08) from TCGA case TCGA-S7-A7WX, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 52.5 years (19,190 days).
Specimen TCGA-S7-A7WX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eac49b40-38af-4913-989c-e03f82e383cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S7-A7WX-10A (Blood Derived Normal), aliquot TCGA-S7-A7WX-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ff9630b-88b2-411b-88af-75b19522110f

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2, Nonstop Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCND2 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs972799571; called by muse, mutect2
- PIGW | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 24/57 reads (42%) | catalogued as rs747591955; called by muse, mutect2, varscan2
- P2RY1 | c.1120T>A p.*374Rext*31 | Nonstop Mutation (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- PRPH2 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LAMA5 | c.10026G>A p.Q3342= | Silent (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- MICAL2 | c.1236C>T p.A412= | Silent (SNP) | VAF 8/117 reads (7%) | called by muse, mutect2
